Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6168, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6168-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with [REDACTED], colonoscopy on [REDACTED] showed 3cm semi-circumferential mass 10cm from ileocecal valve, cecal adenocarcinoma.

Specimens Submitted:

1: SP:Right colon; hemicolectomy

DIAGNOSIS:

1. SP:Right colon; hemicolectomy:

Tumor Type:

Adenocarcinoma with mucinous features (<50% mucinous component)

Histologic Grade:

Moderately differentiated

Tumor Location:

Ascending colon

Tumor Size:

Length is 2.1 cm

Width is 2.8 cm

Maximal thickness is 0.4 cm

Tumor Budding:

Absent

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubular adenoma

Deepest Tumor Invasion:

Subserosal adipose tissue and/or mesenteric fat

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Identified

Large Venous Invasion:

Not Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

Not Identified

** Continued on next page **

[page 2 of 3]
[REDACTED]

Non-Neoplastic Bowel:

Unremarkable

Appendix:

Unremarkable

Lymph Nodes:

Number with metastasis: 0

Total number examined: 31

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N0 (No regional lymph node metastasis)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

1). The specimen is received fresh, labeled "Right colon" and consists of a segment of terminal ileum, cecum with attached appendix and ascending colon. The terminal ileum measures 12.0 cm in length and 3.6 cm in circumference at the proximal resected margin. The remaining colon measures 14.0 in length with a circumference of 5.4 cm at the distal resected margin. The attached appendix measures 5.8 cm in length and averages 0.7 cm in diameter. The appendiceal and intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to the 3.8 cm in thickness. The specimen is opened to reveal a mass lesion measuring 2.1 cm in length and 2.8 cm in width. The mass is located in the right colon, 3.8 cm distal to the ileocecal valve, 17.0 cm from the proximal margin and 6.5 cm from the distal margin. Sectioning shows that the tumor invades the underlying muscularis. The depth of invasion is 0.5 cm grossly. The remaining mucosa is remarkable for a 0.7 x 0.1 to 0.4 cm sessile polyp 1.0 cm distal to the tumor. The attached adipose tissue is thoroughly examined and all identified lymph nodes are submitted. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:

P - proximal margin shave

D - distal margin shave

T - tumor

A - appendix representative sections

** Continued on next page **

[page 3 of 3]
PL- polyp
RS -representative sections
LN - lymph nodes
BLN - bisected lymph nodes

Summary of Sections:
Part 1: SP:Right colon; hemicolectomy

Block	Sect.	Site	PCs
1		A	1
2		D	2
1		DV	1
8		LN	36
1		P	1
1		PL	1
1		RS	1
3		T	3

** End of Report **

Source: NCI Genomic Data Commons file bb62f643-1e87-4756-9668-01a0a700a110 (TCGA-CM-6168.699E7E12-232F-454C-8F1B-6278DF9BCC52.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).